Somatic mutation profile of tumor specimen TCGA-78-7162-01A (aliquot TCGA-78-7162-01A-21D-2063-08) from TCGA case TCGA-78-7162, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 75.5 years (27,593 days).
Specimen TCGA-78-7162-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b4ad7cb-594a-4876-b218-e4303162246f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-78-7162-11A (Solid Tissue Normal), aliquot TCGA-78-7162-11A-01D-2063-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd356323-7ae6-4429-a8ea-a5572c44301c

The open-access MAF lists 90 somatic variants for this specimen: 67 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 21, Frame Shift Del 2, Nonsense Mutation 2, Frame Shift Ins 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADRA1B | c.242A>G p.N81S | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60701278; called by muse, mutect2
- ATAD2B | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53197207, COSV99476875; called by muse, mutect2, varscan2
- CAST | c.123G>C p.K41N | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV57784834; called by muse, mutect2
- CFAP221 | c.2077G>C p.E693Q | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.656); catalogued as COSV54656302; called by muse, mutect2
- CHD2 | c.5165A>T p.D1722V | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV67708216; called by muse, mutect2, varscan2
- COL11A2 | c.2134G>A p.G712R (on ENST00000341947 / NM_080680.3; = p.G605R on NM_080679.2) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV59495755; called by muse, mutect2
- CRIM1 | c.2651T>C p.I884T | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs1316495060, COSV54862437; called by muse, mutect2
- CSMD1 | c.7433C>G p.P2478R (on ENST00000520002; = p.P2477R on NM_033225.6) | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV59308463; called by muse, mutect2, varscan2
- CSMD3 | c.8386G>C p.V2796L (on ENST00000297405 / NM_001363185.1; = p.V2627L on NM_052900.3) | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1359158313, COSV52153195; called by muse, mutect2, varscan2
- CUL9 | c.7238G>T p.R2413L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV52727575; called by muse, mutect2
- CUX1 | c.1024G>T p.E342* (on ENST00000292535 / NM_181552.4; = p.E353* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 11/49 reads (22%) | catalogued as COSV52896460, COSV52901664; called by muse, mutect2, varscan2
- EFHC1 | c.106G>T p.G36C | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64136049; called by muse, mutect2, varscan2
- EPHA5 | c.1705C>A p.Q569K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV56630395, COSV56639966; called by muse, mutect2, varscan2
- GPR137B | c.283C>A p.L95I | Missense Mutation (SNP) | VAF 26/188 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63990851; called by muse, mutect2, varscan2
- GPX6 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.746); catalogued as COSV62657272; called by muse, mutect2
- GRB10 | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV60010281; called by mutect2, varscan2
- GRB2 | c.481G>T p.V161F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV57304136; called by muse, mutect2, varscan2
- ITIH6 | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV54488247; called by muse, mutect2, varscan2
- KALRN | c.5135G>C p.R1712P | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV62564360; called by muse, mutect2, varscan2
- KATNBL1 | c.43A>G p.N15D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV56622838; called by muse, mutect2, varscan2
- KEAP1 | c.475G>T p.A159S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.873); catalogued as COSV50277303, COSV50652664, COSV99408437; called by muse, mutect2, varscan2
- KHSRP | c.2099C>T p.P700L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.07); catalogued as rs779255957, COSV67919582; called by muse, mutect2, varscan2
- KLHL18 | c.1585G>T p.V529F | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51745021; called by muse, mutect2, varscan2
- KRTAP21-1 | c.43G>T p.G15C | Missense Mutation (SNP) | VAF 40/204 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as COSV58645871, COSV58646235; called by muse, mutect2, varscan2
- LY9 | c.1765T>C p.Y589H | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.374); catalogued as COSV54433361; called by muse, mutect2
- MAN2A2 | c.2587G>A p.V863M | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as rs148275760; called by muse, mutect2
- MORC4 | c.1586G>A p.G529E | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV55241112; called by muse, mutect2, varscan2
- NBPF3 | c.1097A>T p.D366V | Missense Mutation (SNP) | VAF 35/265 reads (13%) | SIFT tolerated (0.27); PolyPhen benign (0.091); catalogued as COSV59058280; called by muse, mutect2, varscan2
- OR2M5 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 115/529 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63546057; called by muse, mutect2, varscan2
- OR5K2 | c.689C>A p.S230Y | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.443); catalogued as COSV71143130; called by muse, mutect2
- PCDHGB5 | c.769C>A p.P257T | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.783); catalogued as COSV53929125; called by muse, mutect2, varscan2
- PCLO | c.5215G>A p.E1739K | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV61627841; called by muse, mutect2
- PDE5A | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs569083571, COSV53347254; called by muse, mutect2, varscan2
- PLAA | c.566G>T p.G189V | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101263470, COSV68304751; called by muse, mutect2
- PTPRC | c.271G>C p.D91H | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV61409604; called by muse, mutect2, varscan2
- RAPGEF6 | c.1193T>C p.M398T | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.253); catalogued as COSV57244142; called by muse, mutect2
- RBFOX1 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV60954830; called by muse, mutect2, varscan2
- RUVBL1 | c.979G>A p.V327I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.304); catalogued as COSV59475635; called by muse, mutect2, varscan2
- SCUBE2 | c.3049C>G p.R1017G (on ENST00000649792 / NM_001367977.2; = p.R960G on NM_020974.3) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV100496211, COSV58541972; called by muse, mutect2, varscan2
- SEMA6C | c.1529G>C p.C510S | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV59001922; called by muse, mutect2
- SLC25A18 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.208); catalogued as COSV53657674; called by muse, mutect2
- SMG8 | c.2678C>T p.S893L | Missense Mutation (SNP) | VAF 9/176 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.868); catalogued as COSV56284865; called by muse, mutect2
- SPATA17 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100861186, COSV65121044; called by muse, mutect2
- STEAP1 | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV51881399; called by muse, mutect2
- SUSD5 | c.854G>C p.G285A | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV58876955; called by muse, mutect2
- SYT9 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 12/315 reads (4%) | SIFT tolerated (0.88); PolyPhen benign (0.001); catalogued as COSV59616614; called by muse, mutect2
- TEDDM1 | c.53A>C p.Q18P | Missense Mutation (SNP) | VAF 34/162 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV62380430; called by muse, mutect2, varscan2
- TMEM132D | c.1032T>A p.D344E | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as COSV70601174; called by muse, mutect2
- TMEM41B | c.132G>T p.W44C | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV55154931; called by mutect2, varscan2
- TMX3 | c.1240A>G p.K414E | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.03); catalogued as rs965082154, COSV55184878; called by muse, mutect2, varscan2
- TNN | c.2277G>C p.Q759H | Missense Mutation (SNP) | VAF 7/154 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV53423218, COSV53424598; called by muse, mutect2
- TRPV5 | c.652C>A p.L218M | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as COSV54684751, COSV54689657; called by muse, mutect2, varscan2
- TSHZ3 | c.767A>C p.K256T | Missense Mutation (SNP) | VAF 40/283 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53668963; called by muse, mutect2, varscan2
- UBXN4 | c.1205C>T p.S402F | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV99739778; called by muse, mutect2
- ULK4 | c.1323A>T p.K441N | Missense Mutation (SNP) | VAF 19/149 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.614); catalogued as COSV57205366; called by muse, mutect2, varscan2
- VWA3A | c.2641T>A p.C881S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV100240807, COSV55395337; called by muse, mutect2
- YTHDF2 | c.610C>G p.P204A | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.108); catalogued as COSV65723003, COSV65723074; called by muse, mutect2, varscan2
- ZEB1 | c.3067G>A p.D1023N | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58041731; called by muse, mutect2
- ZFP14 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.73); PolyPhen benign (0.357); catalogued as rs751723890, COSV54202645, COSV99525395; called by muse, mutect2, varscan2
- ZFX | c.1702A>T p.R568* | Nonsense Mutation (SNP) | VAF 17/82 reads (21%) | catalogued as COSV58447131; called by muse, mutect2, varscan2
- ZNF365 | c.422G>A p.G141E | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.86); PolyPhen benign (0.011); catalogued as COSV101237947, COSV101238009; called by muse, mutect2, varscan2
- ARNT | c.1740_1744del p.Q581Afs*21 | Frame Shift Del (DEL) | VAF 20/97 reads (21%) | called by mutect2, pindel, varscan2
- CNOT9 | c.268G>T p.V90F | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GRB10 | c.493dup p.A165Gfs*7 | Frame Shift Ins (INS) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- KCNG2 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2
- NTNG1 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.44); called by muse, mutect2
- STK31 | c.603del p.E202Rfs*58 | Frame Shift Del (DEL) | VAF 19/129 reads (15%) | called by mutect2, pindel, varscan2
- ADD1 | c.381G>C p.V127= | Silent (SNP) | VAF 10/232 reads (4%) | catalogued as COSV53268123, COSV53269092; called by muse, mutect2
- ATP6V1G1 | c.201C>T p.G67= | Silent (SNP) | VAF 8/84 reads (10%) | catalogued as COSV65014074; called by muse, mutect2
- BMPER | c.588A>T p.T196= | Silent (SNP) | VAF 18/160 reads (11%) | catalogued as COSV51815857; called by muse, mutect2, varscan2
- CFHR5 | c.1422G>A p.V474= | Silent (SNP) | VAF 9/169 reads (5%) | catalogued as COSV56820665; called by muse, mutect2
- CRYBB1 | c.54G>A p.G18= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as COSV53233002; called by muse, mutect2, varscan2
- DAG1 | c.447C>T p.S149= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV58183604; called by muse, mutect2, varscan2
- EFR3A | c.1905T>C p.F635= | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV54455717; called by muse, mutect2, varscan2
- GPR179 | c.495G>A p.Q165= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- IGKV2D-29 | c.30G>T p.L10= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as rs1211018085; called by muse, mutect2, varscan2
- KPNA1 | c.834C>T p.L278= | Silent (SNP) | VAF 4/73 reads (5%) | catalogued as COSV60268496; called by muse, mutect2
- MAP4K3 | c.2490G>A p.V830= | Silent (SNP) | VAF 13/117 reads (11%) | catalogued as COSV55711991; called by muse, mutect2, varscan2
- PCDHGA2 | c.2046C>A p.A682= | Silent (SNP) | VAF 10/226 reads (4%) | catalogued as COSV53929113; called by muse, mutect2
- POLR3H | c.546T>G p.A182= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as COSV53442363; called by muse, mutect2, varscan2
- PTPRB | c.2643C>A p.G881= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV54238482; called by muse, mutect2, varscan2
- STAG3 | c.2067C>A p.S689= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as COSV57929165; called by muse, mutect2, varscan2
- TACR3 | c.1002C>T p.I334= | Silent (SNP) | VAF 18/96 reads (19%) | catalogued as COSV59200262; called by muse, mutect2, varscan2
- UBXN4 | c.1206C>T p.S402= | Silent (SNP) | VAF 10/148 reads (7%) | catalogued as COSV99739784; called by muse, mutect2
- UGT1A5 | c.807C>A p.I269= | Silent (SNP) | VAF 47/252 reads (19%) | catalogued as COSV59386582; called by muse, mutect2, varscan2
- ZFP14 | c.552C>T p.R184= | Silent (SNP) | VAF 20/160 reads (13%) | catalogued as COSV99525393; called by muse, mutect2, varscan2
- ZNF236 | c.5169A>G p.K1723= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV53486073; called by muse, mutect2, varscan2
- ZNF695 | c.228C>T p.N76= | Silent (SNP) | VAF 10/114 reads (9%) | catalogued as rs747883899, COSV60585482; called by muse, mutect2
- KIAA1217 | c.354+55812G>A | Intron (SNP) | VAF 8/32 reads (25%) | catalogued as COSV64604022; called by muse, mutect2, varscan2
- MIR1270 | chr19:20397431 G>T | 3'Flank (SNP) | VAF 5/58 reads (9%) | called by muse, mutect2
